Gene-level copy-number profile of specimen HCM-BROD-0445-C15-85M from HCMI case HCM-BROD-0445-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.0 years (20,467 days).
Specimen HCM-BROD-0445-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45d954c8-5666-40a1-b9fe-ef3eb1579e55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0445-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/11fdb345-7f61-476d-88e9-c44af37d29bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,786; copy number 2: 23,289; copy number 3: 16,885; copy number 4: 9,449; copy number 5: 4,383; copy number 6: 431; copy number 7: 243; copy number 8: 125; copy number 9: 213; copy number 23: 4; copy number 24: 4; copy number 25: 88.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,491 genes in 69 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,593,243–26,647,681, 6 genes, copy number 5: RN7SL679P, Y_RNA, RNU7-29P, AL627313.1, AL627082.2, AL627082.1.
- chr1:119,834,870–120,850,985, 21 genes, copy number 5–6: NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19.
- chr2:156,324,437–157,380,414, 8 genes, copy number 5: NR4A2, GPD2, RPLP0P7, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP.
- chr2:157,526,767–158,753,775, 20 genes, copy number 5: ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2.
- chr2:160,849,313–162,838,767, 34 genes, copy number 5 (within-gene range 4–5): AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2, SLC4A10, AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109.
- chr2:164,895,677–165,689,407, 6 genes, copy number 5: RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, CSRNP3.
- chr2:168,786,539–169,526,258, 11 genes, copy number 5 (within-gene range 4–5): NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2, BBS5, AC093899.2, KLHL41.
- chr2:172,735,274–173,576,341, 11 genes, copy number 5 (within-gene range 4–5): RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1.
- chr2:174,072,447–174,310,974, 6 genes, copy number 5: OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39.
- chr2:182,909,115–183,495,501, 10 genes, copy number 5: NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1.
- chr2:188,598,791–189,784,364, 22 genes, copy number 5 (within-gene range 4–5): AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1.
- chr2:189,879,609–191,425,389, 28 genes, copy number 5 (within-gene range 4–5): C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B.
- chr2:195,003,711–196,176,503, 14 genes, copy number 5: AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2.
- chr2:208,108,233–208,222,625, 9 genes, copy number 5: CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2.
- chr2:225,698,254–226,799,759, 7 genes, copy number 5: AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1.
- chr2:241,970,683–242,160,153, 9 genes, copy number 7: LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:166,160,021–173,336,965, 123 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr3:175,938,929–196,211,437, 398 genes, copy number 5 (broad region; genes not listed).
- chr3:197,298,252–198,123,232, 31 genes, copy number 5–6 (within-gene range 2–6): DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr7:37,032–8,344,516, 199 genes, copy number 5–6 (broad region; genes not listed).
- chr7:8,938,787–30,892,387, 337 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:32,788,334–36,841,373, 72 genes, copy number 7–8 (broad region; genes not listed).
- chr7:37,683,796–44,920,329, 143 genes, copy number 5–8 (broad region; genes not listed).
- chr7:73,985,992–74,405,935, 9 genes, copy number 5: AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, CLIP2.
- chr7:76,201,896–76,650,897, 17 genes, copy number 5: SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2.
- chr7:76,959,835–77,995,171, 28 genes, copy number 5: DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1.
- chr7:80,096,600–81,335,183, 14 genes, copy number 5: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1.
- chr7:83,955,777–86,217,733, 14 genes, copy number 5: SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:87,322,943–87,832,296, 8 genes, copy number 5: TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B.
- chr7:142,462,916–142,627,399, 24 genes, copy number 5: TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1.
- chr8:37,326,575–88,887,573, 790 genes, copy number 5 (broad region; genes not listed).
- chr8:89,585,872–145,066,685, 871 genes, copy number 5 (broad region; genes not listed).
- chr11:76,591,023–78,582,156, 59 genes, copy number 5–6: AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:112,165,197–120,489,937, 235 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr15:21,328,380–21,951,323, 36 genes, copy number 6: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr17:37,609,739–43,014,456, 312 genes, copy number 5–25 (broad region; genes not listed).
- chr18:45,034–2,049,510, 47 genes, copy number 6 (within-gene range 3–6): AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:21,242,242–24,162,211, 66 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:87,250–13,996,443, 277 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:16,670,641–64,327,972, 1,100 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
